Somatic mutation profile of tumor specimen 0DMRB6 from CCDI case PBCARS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.5 years (5,646 days).
Specimen 0DMRB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9b015c2-ff29-46ca-8c76-5f231787d6f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMRAQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2318eaf-4bb4-4128-9eb5-6041c8d8db63

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Splice Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 162/596 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs769756628; called by muse, mutect2, varscan2
- ADGB | c.4838G>T p.R1613L | Missense Mutation (SNP) | VAF 241/895 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754776474, COSV62235294; called by muse, mutect2
- ATP7B | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 86/1282 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs559705781, COSV54441307; called by muse, mutect2
- DCAF8L2 | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 211/224 reads (94%) | SIFT tolerated (0.78); PolyPhen benign (0.06); catalogued as COSV99070011; called by muse, mutect2, varscan2
- DHX30 | c.2287-1G>A p.X763_splice (on ENST00000445061 / NM_138615.3; = p.X724_splice on NM_014966.3) | Splice Site (SNP) | VAF 263/630 reads (42%) | catalogued as COSV99275627; called by muse, mutect2, varscan2
- FBN3 | c.6583G>A p.G2195S | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764047610; called by muse, mutect2, varscan2
- GRM5 | c.2285G>T p.R762I | Missense Mutation (SNP) | VAF 261/661 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59590034, COSV59601109; called by muse, mutect2, varscan2
- HECW2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 24/652 reads (4%) | catalogued as COSV53650291; called by muse, mutect2
- KIN | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 223/895 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1330958934; called by muse, mutect2, varscan2
- KLF18 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 224/565 reads (40%) | SIFT deleterious (0); catalogued as rs376287364; called by muse, mutect2, varscan2
- MAST2 | c.4445G>A p.R1482Q | Missense Mutation (SNP) | VAF 159/326 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as rs770025915; called by muse, mutect2, varscan2
- SRRT | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 189/565 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs766065934, COSV99574084; called by muse, mutect2, varscan2
- TET1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV65386962; called by muse, mutect2, varscan2
- ZSWIM8 | c.3068C>T p.T1023M (on ENST00000605216 / NM_001242487.2; = p.T1028M on NM_015037.3) | Missense Mutation (SNP) | VAF 173/559 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs757744420, COSV101290001; called by muse, mutect2, varscan2
- ADAMTS19 | c.2662C>A p.L888M | Missense Mutation (SNP) | VAF 231/534 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- AFF1 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 140/395 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ATF5 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 118/517 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP8A1 | c.3389A>G p.N1130S | Missense Mutation (SNP) | VAF 74/547 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf22 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 122/510 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCNK | c.1472C>A p.P491Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A3 | c.2135G>T p.G712V | Missense Mutation (SNP) | VAF 141/526 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CRACR2A | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 289/874 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CRNKL1 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 287/956 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MN1 | c.3206T>A p.L1069Q | Missense Mutation (SNP) | VAF 42/975 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NFXL1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 125/298 reads (42%) | called by muse, varscan2
- PCNX1 | c.6587C>T p.S2196F | Missense Mutation (SNP) | VAF 175/439 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RYR1 | c.9200G>A p.C3067Y | Missense Mutation (SNP) | VAF 226/1241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- SFMBT2 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 247/769 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC22A3 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 203/714 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLIT1 | c.3037G>T p.A1013S | Missense Mutation (SNP) | VAF 80/574 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 180/485 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPEG | c.4993G>A p.E1665K | Missense Mutation (SNP) | VAF 245/816 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SUSD3 | c.273C>A p.C91* | Nonsense Mutation (SNP) | VAF 166/355 reads (47%) | called by muse, mutect2, varscan2
- THBS2 | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 129/974 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- TMEM215 | c.187A>C p.T63P | Missense Mutation (SNP) | VAF 14/496 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UBAP2L | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 187/941 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CEP250 | c.2748A>T p.L916= | Silent (SNP) | VAF 211/721 reads (29%) | called by muse, mutect2, varscan2
- DNAH2 | c.2061C>T p.A687= | Silent (SNP) | VAF 213/504 reads (42%) | catalogued as rs1315467117; called by muse, mutect2, varscan2
- IL1RL2 | c.1374C>A p.G458= | Silent (SNP) | VAF 99/977 reads (10%) | called by muse, mutect2, varscan2
- KRT6A | c.546G>C p.R182= | Silent (SNP) | VAF 27/1057 reads (3%) | called by muse, mutect2
- LDHA | c.102C>T p.A34= | Silent (SNP) | VAF 361/623 reads (58%) | called by muse, mutect2, varscan2
- N4BP1 | c.2436G>A p.P812= | Silent (SNP) | VAF 272/602 reads (45%) | catalogued as rs533936254; called by muse, mutect2, varscan2
- NCOA3 | c.1725C>T p.C575= | Silent (SNP) | VAF 217/810 reads (27%) | catalogued as rs368779000; called by muse, mutect2, varscan2
- ROR1 | c.1305G>A p.S435= | Silent (SNP) | VAF 95/632 reads (15%) | catalogued as rs768590709, COSV64284917; called by muse, mutect2, varscan2
- SPTA1 | c.427C>T p.L143= | Silent (SNP) | VAF 106/1019 reads (10%) | catalogued as COSV100935181; called by muse, mutect2, varscan2
- TDRD9 | c.3705G>A p.V1235= | Silent (SNP) | VAF 129/292 reads (44%) | catalogued as rs1455388899; called by muse, mutect2, varscan2
- TLE4 | c.*40G>C | 3'UTR (SNP) | VAF 34/435 reads (8%) | called by muse, mutect2
- ZNF724 | c.-34C>A | 5'UTR (SNP) | VAF 194/948 reads (20%) | catalogued as COSV101370042; called by muse, mutect2, varscan2
